Somatic mutation profile of tumor specimen TCGA-04-1652-01A (aliquot TCGA-04-1652-01A-01W-0639-09) from TCGA case TCGA-04-1652, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 76.9 years (28,101 days).
Specimen TCGA-04-1652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd9360cf-1947-4d25-8c72-b055c7076738.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1652-11A (Solid Tissue Normal), aliquot TCGA-04-1652-11A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49f78d75-43fb-4eee-aae4-9706ab3ebb7c

The open-access MAF lists 83 somatic variants for this specimen: 55 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 27, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRT | c.1643A>G p.E548G | Missense Mutation (SNP) | VAF 46/242 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV62029071; called by muse, mutect2, varscan2
- TP53 | c.526T>G p.C176G | Missense Mutation (SNP) | VAF 72/81 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967461896, CM165714, COSV52681947, COSV52682539, COSV52736779, COSV52752470; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV51113501; called by muse, mutect2, varscan2
- ANKRD34B | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as rs376632230; called by muse, mutect2, varscan2
- CEP104 | c.1558C>A p.L520I | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.359); catalogued as COSV100986595; called by muse, mutect2
- DCLK1 | c.220T>A p.Y74N | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99710006; called by muse, mutect2
- DLK2 | c.921G>T p.L307F | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV55094819; called by muse, mutect2, varscan2
- DST | c.1922A>T p.H641L (on ENST00000361203 / NM_001374722.1; = p.H315L on NM_001723.6) | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55045305; called by muse, mutect2, varscan2
- DUSP5 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 44/461 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs377294017; called by muse, mutect2, varscan2
- HAO2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.16); catalogued as rs770017018, COSV58041356; called by muse, mutect2, varscan2
- HDHD2 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 13/367 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1364192043, COSV100321269; called by muse, mutect2
- HIPK3 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 120/378 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV57566430; called by muse, varscan2
- IFNA21 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 143/385 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.275); catalogued as COSV66518485, COSV66519113; called by muse, mutect2, varscan2
- LRP1B | c.10295-1G>A p.X3432_splice | Splice Site (SNP) | VAF 74/192 reads (39%) | catalogued as COSV67248326, COSV67281791; called by muse, mutect2, varscan2
- MAGEA11 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100290432, COSV60754019; called by muse, mutect2, varscan2
- MAP7D3 | c.1535G>A p.S512N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as COSV100286256; called by muse, mutect2, varscan2
- MINDY3 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99510610; called by muse, mutect2, varscan2
- MLEC | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 23/280 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as COSV99949604; called by muse, mutect2
- MUC20 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1358507648, COSV57854930; called by muse, mutect2, varscan2
- MUC5B | c.8093C>T p.T2698M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.848); catalogued as rs767471120, COSV101500179; called by muse, varscan2
- MYH1 | c.5599A>G p.R1867G | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56843202, COSV99875372; called by muse, mutect2
- MYO6 | c.2783G>A p.R928H | Missense Mutation (SNP) | VAF 84/305 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs760672339, COSV64117739; called by muse, mutect2, varscan2
- NES | c.2296C>T p.R766W | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as rs767060003, COSV63960664, COSV63963303; called by muse, mutect2, varscan2
- NMUR2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776110616, COSV54919667; called by muse, mutect2, varscan2
- NOP14 | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100054472; called by muse, mutect2
- NRCAM | c.916A>G p.K306E (on ENST00000379028 / NM_001371124.1; = p.K300E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100694496; called by muse, mutect2
- OR11A1 | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 63/365 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV65821428; called by muse, mutect2, varscan2
- OR2T33 | c.667G>C p.V223L | Missense Mutation (SNP) | VAF 10/329 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100531740; called by muse, mutect2
- OR4C12 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 95/543 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV58859646; called by muse, mutect2, varscan2
- OR51E1 | c.68T>A p.L23* | Nonsense Mutation (SNP) | VAF 86/862 reads (10%) | catalogued as COSV101211480; called by muse, mutect2
- OR5W2 | c.748A>G p.I250V | Missense Mutation (SNP) | VAF 15/331 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.12); catalogued as COSV100747574, COSV100747591; called by muse, mutect2
- PDE1C | c.334C>T p.R112W | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs964367849, COSV100372251, COSV58513919; called by muse, mutect2, varscan2
- PTPN21 | c.2531T>C p.V844A | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752269385, COSV60852610; called by muse, mutect2, varscan2
- PTPRZ1 | c.2596G>T p.D866Y | Missense Mutation (SNP) | VAF 59/306 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV66447044; called by muse, mutect2, varscan2
- RPS9 | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV57191032; called by muse, mutect2, varscan2
- SLC5A7 | c.1132G>A p.V378I | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as rs763020957, COSV50890306; called by muse, mutect2, varscan2
- SLCO3A1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV59238850; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.431T>G p.F144C | Missense Mutation (SNP) | VAF 22/396 reads (6%) | PolyPhen probably damaging (0.992); catalogued as COSV100082380; called by muse, mutect2
- SYNE2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV59973198; called by muse, mutect2, varscan2
- TACC2 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs758575064, COSV57758447; called by muse, mutect2, varscan2
- TG | c.1432G>T p.V478L | Missense Mutation (SNP) | VAF 33/546 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV99599874; called by muse, mutect2
- TSGA10IP | c.422T>C p.F141S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV73245449; called by muse, mutect2, varscan2
- TTLL2 | c.271G>A p.V91I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as rs140657695; called by muse, mutect2, varscan2
- UNC50 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100158638; called by muse, mutect2
- UNC79 | c.7735C>T p.L2579F (on ENST00000393151 / NM_001346218.2; = p.L2402F on NM_020818.5) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99826666; called by muse, mutect2
- UPRT | c.405C>G p.D135E | Missense Mutation (SNP) | VAF 34/384 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as COSV100974469; called by muse, mutect2
- XAB2 | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV64322315; called by muse, mutect2, varscan2
- XCR1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs140218706, COSV58569310; called by muse, mutect2, varscan2
- ZC3H12C | c.1058A>G p.N353S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760228663, COSV53708972; called by muse, mutect2, varscan2
- ZCWPW1 | c.631+1G>A p.X211_splice | Splice Site (SNP) | VAF 58/238 reads (24%) | catalogued as rs774275324, COSV61249078; called by muse, mutect2, varscan2
- DEUP1 | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- FAT3 | c.8430_8432del p.N2810del | In Frame Del (DEL) | VAF 12/100 reads (12%) | called by pindel, varscan2
- MAP2K7 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- MPEG1 | c.1235del p.C412Sfs*77 | Frame Shift Del (DEL) | VAF 31/222 reads (14%) | called by mutect2, varscan2
- ZNF628 | c.2567T>C p.L856P | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2
- ADAMTS5 | c.1698C>T p.S566= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as rs754975853, COSV53179706, COSV53186263; called by muse, mutect2, varscan2
- ANO2 | c.2310C>T p.N770= (on ENST00000356134 / NM_001278597.3; = p.N774= on NM_001278596.3) | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs377226128; called by muse, mutect2, varscan2
- CCNB3 | c.1947G>A p.L649= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs201598054, COSV52080758; called by mutect2, varscan2
- CDH9 | c.2043G>A p.E681= | Silent (SNP) | VAF 89/342 reads (26%) | catalogued as COSV50520399; called by muse, mutect2, varscan2
- CEP131 | c.399C>T p.P133= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs1182497599, COSV53956931, COSV99488423; called by muse, mutect2, varscan2
- CEP350 | c.8022A>C p.T2674= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as COSV100854422; called by muse, mutect2
- CHIA | c.1005C>G p.G335= (on ENST00000343320; = p.G227= on NM_021797.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 91/238 reads (38%) | catalogued as COSV58478841; called by muse, mutect2, varscan2
- COL16A1 | c.2292C>T p.P764= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs757782497, COSV54713151; called by mutect2, varscan2
- CSMD1 | c.8604C>T p.N2868= (on ENST00000520002; = p.N2867= on NM_033225.6) | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs368720706; called by muse, mutect2, varscan2
- CSNK1E | c.381G>T p.R127= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV63292288; called by muse, mutect2, varscan2
- DNAH11 | c.8262A>G p.K2754= | Silent (SNP) | VAF 37/272 reads (14%) | catalogued as COSV60965867, COSV60986092; called by muse, mutect2, varscan2
- DPP6 | c.996C>T p.T332= (on ENST00000377770 / NM_001364500.2; = p.T270= on NM_001936.5) | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs371237236; called by muse, mutect2, varscan2
- DRD5 | c.894G>T p.L298= | Silent (SNP) | VAF 4/91 reads (4%) | called by muse, mutect2
- FNBP1 | c.255G>T p.G85= | Silent (SNP) | VAF 4/76 reads (5%) | catalogued as COSV100852625; called by muse, mutect2
- HEPH | c.1122G>A p.L374= (on ENST00000343002; = p.L107= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV57973793; called by muse, mutect2, varscan2
- NHLRC1 | c.966C>A p.A322= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV61481927; called by muse, mutect2, varscan2
- PCDHGB2 | c.1080G>A p.S360= | Silent (SNP) | VAF 42/165 reads (25%) | catalogued as COSV53957153; called by muse, mutect2, varscan2
- PHIP | c.2229G>A p.K743= | Silent (SNP) | VAF 13/217 reads (6%) | catalogued as COSV99243714; called by muse, mutect2
- POU2F3 | c.279G>A p.P93= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs778742308, COSV52792738; called by muse, mutect2, varscan2
- PPARGC1A | c.1077C>T p.S359= | Silent (SNP) | VAF 55/212 reads (26%) | catalogued as COSV53534424; called by muse, mutect2, varscan2
- PRPSAP1 | c.675C>T p.A225= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs781680969, COSV100221668; called by muse, mutect2
- RIMS2 | c.3342G>A p.T1114= (on ENST00000666250 / NM_001348490.2; = p.T922= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as rs1336539202, COSV51729885, COSV99165237; called by muse, mutect2
- SCN3A | c.1197A>T p.T399= | Silent (SNP) | VAF 34/275 reads (12%) | catalogued as COSV51827098; called by muse, mutect2, varscan2
- THOC2 | c.12G>A p.A4= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs770941379, COSV55557109; called by muse, mutect2, varscan2
- TLR7 | c.1740T>C p.F580= | Silent (SNP) | VAF 43/371 reads (12%) | catalogued as COSV66125772; called by muse, mutect2, varscan2
- VRK2 | c.564A>G p.G188= | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as COSV100417556; called by muse, mutect2
- WASHC2A | c.1248G>A p.T416= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs781980747; called by muse, mutect2, varscan2
- SNORD116-3 | n.74G>A | RNA (SNP) | VAF 73/180 reads (41%) | catalogued as rs568283973; called by muse, mutect2, varscan2
